Somatic mutation profile of tumor specimen BA2071D (aliquot aq-BA2071D) from BEATAML1.0 case 2459, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Myelodysplastic syndrome, unclassifiable; Tissue or organ of origin: Bone marrow; Age at diagnosis: 40.2 years (14,694 days).
Specimen BA2071D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e8d3342-3dfd-49ea-a2e1-1b346131855d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2983D (Solid Tissue Normal), aliquot aq-BA2983D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b33ca53e-2f0c-40d1-9339-1fc2ecaa247c

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- COLEC12 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs996591543, COSV68374876; called by muse, mutect2, varscan2
- SPATA6 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs777236752, COSV64062426; called by muse, mutect2, varscan2
- TSHR | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs137908024; called by muse, mutect2, varscan2
- ANKRD49 | c.337C>A p.H113N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP299 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, varscan2
- DNAH17 | c.2800G>T p.D934Y | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- EZR | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SRCAP | c.6698_6699del p.V2233Gfs*18 | Frame Shift Del (DEL) | VAF 17/145 reads (12%) | called by pindel, varscan2
- C1orf116 | c.1557G>T p.S519= | Silent (SNP) | VAF 7/172 reads (4%) | catalogued as rs1179489476, COSV63943702; called by muse, mutect2
- CLTRN | c.240G>A p.R80= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- SBNO2 | c.2430C>T p.A810= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as rs756233278; called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25091984 C>A | 3'Flank (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
